Somatic mutation profile of tumor specimen 506131e8-6460-472f-9e25-71f8b1 (aliquot 506131e8-6460-472f-9e25-71f8b1_D6_2) from CPTAC case 05CO047, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen 506131e8-6460-472f-9e25-71f8b1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b4ef7aa-17db-4eb0-b06d-4020816ffbe5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f01e8a3e-9003-45dd-9f3e-5ad6a6 (Blood Derived Normal), aliquot f01e8a3e-9003-45dd-9f3e-5ad6a6_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dd34231-510e-45c2-9781-1e55e5078666

The open-access MAF lists 86 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 15, Intron 6, Nonsense Mutation 6, Frame Shift Del 2, Frame Shift Ins 2, RNA 1, In Frame Del 1, 3'Flank 1, 3'UTR 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 167/252 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 104/242 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 163/328 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 176/268 reads (66%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1484C>G p.T495R | Missense Mutation (SNP) | VAF 161/375 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53965326; called by muse, mutect2, varscan2
- ADNP | c.3047dup p.A1017Gfs*6 | Frame Shift Ins (INS) | VAF 40/183 reads (22%) | catalogued as rs761350619; called by mutect2, varscan2
- AL136295.1 | c.2434C>T p.L812F | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV55778233, COSV55781965; called by muse, mutect2, varscan2
- APC | c.3814dup p.S1272Ffs*4 | Frame Shift Ins (INS) | VAF 88/220 reads (40%) | catalogued as CI058181; called by mutect2, varscan2
- APC2 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs565588972; called by muse, mutect2, varscan2
- CDH24 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs1242765544, COSV99944076; called by muse, mutect2, varscan2
- CELSR2 | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs764176269; called by muse, mutect2, varscan2
- CPB2 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773350527, COSV99473060; called by muse, mutect2, varscan2
- CPXM1 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs776351140, COSV66045544; called by muse, mutect2, varscan2
- EPHA10 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs761133986, COSV57621826; called by muse, mutect2, varscan2
- FAM184B | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 212/508 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs567559077; called by muse, mutect2, varscan2
- FBXW7 | c.1576T>C p.W526R (on ENST00000281708 / NM_001349798.2; = p.W446R on NM_018315.5) | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55922932; called by muse, varscan2
- ITGB3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 156/374 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs760480847, COSV71383470; called by mutect2, varscan2
- ME1 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757421355, COSV63838920; called by muse, mutect2, varscan2
- MINDY2 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as rs914220356; called by muse, mutect2, varscan2
- MUC16 | c.25187C>A p.S8396Y | Missense Mutation (SNP) | VAF 161/388 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as rs1277244018, COSV101198768; called by muse, mutect2, varscan2
- MYO1C | c.2839G>A p.V947I (on ENST00000648651 / NM_001080779.2; = p.V912I on NM_033375.5) | Missense Mutation (SNP) | VAF 186/296 reads (63%) | SIFT tolerated (0.49); PolyPhen benign (0.097); catalogued as rs757986820; called by muse, mutect2, varscan2
- NLRP4 | c.2629G>A p.G877R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.592); catalogued as rs772913904, COSV56718246; called by muse, mutect2, varscan2
- NPAP1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1191220500, COSV61503920, COSV61506368; called by muse, mutect2, varscan2
- PIANP | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs779280940; called by muse, mutect2, varscan2
- PLEC | c.11972G>A p.R3991H (on ENST00000322810 / NM_201380.4; = p.R3881H on NM_000445.5) | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs782426200, COSV59677577; called by muse, mutect2
- PTPRM | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 155/221 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs756812393; called by muse, mutect2, varscan2
- PYCR1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 271/644 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs748950222, COSV100321371; called by muse, mutect2, varscan2
- RHOBTB1 | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV61959505; called by muse, mutect2, varscan2
- SALL3 | c.3218C>T p.A1073V | Missense Mutation (SNP) | VAF 220/299 reads (74%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1355100039; called by muse, mutect2, varscan2
- SLC4A7 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs372621060; called by muse, mutect2, varscan2
- SPAG16 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 72/206 reads (35%) | catalogued as rs752099484, COSV59078825; called by muse, mutect2, varscan2
- TDRD6 | c.6225G>C p.W2075C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60179028; called by muse, mutect2, varscan2
- TGIF1 | c.184-1G>C p.X62_splice (on ENST00000330513 / NM_001374396.1; = p.X82_splice on NM_003244.4) | Splice Site (SNP) | VAF 121/161 reads (75%) | catalogued as COSV100395018; called by muse, mutect2, varscan2
- TRANK1 | c.7849C>T p.R2617C | Missense Mutation (SNP) | VAF 157/375 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs751367533, COSV57159704; called by muse, mutect2, varscan2
- TTC39A | c.1007G>A p.R336Q (on ENST00000447632 / NM_001297665.1; = p.R301Q on NM_001080494.3) | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs773802039, COSV99396727; called by muse, mutect2, varscan2
- UBR4 | c.8225A>G p.Q2742R | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.838); catalogued as rs767754966; called by muse, mutect2, varscan2
- UBXN11 | c.716G>A p.R239Q (on ENST00000374221 / NM_183008.2; = p.R206Q on NM_145345.2) | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.05); catalogued as rs372332532; called by muse, mutect2
- ZNF469 | c.7006G>A p.A2336T (on ENST00000437464; = p.A2364T on NM_001367624.2) | Missense Mutation (SNP) | VAF 239/582 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs957383204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF540 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs188123185; called by muse, mutect2, varscan2
- AL592490.1 | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 154/381 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ATAD2B | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- CADM2 | c.317T>G p.L106* (on ENST00000407528 / NM_001167674.2; = p.L108* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- CAMTA1 | c.3790G>T p.A1264S | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.197); called by muse, varscan2
- CAPZA1 | c.812G>A p.W271* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- CFAP54 | c.6100C>T p.L2034F | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC27 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ESR1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 172/404 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FAM162B | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by mutect2, varscan2
- FAM181B | c.-15_5del | Translation Start Site (DEL) | VAF 25/60 reads (42%) | called by mutect2, pindel
- FAM184B | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- HAUS3 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- HMX1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ITGAV | c.2172A>T p.L724F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- KLK14 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- MAT2A | c.175_176del p.V59Cfs*2 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | called by mutect2, pindel, varscan2
- NDNF | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NFX1 | c.2066A>G p.N689S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAPGEF5 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 210/672 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.289); called by mutect2, varscan2
- RAX | c.608del p.K203Sfs*82 | Frame Shift Del (DEL) | VAF 50/85 reads (59%) | called by mutect2, pindel, varscan2
- RBMXL2 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 112/297 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- UGT2B28 | c.236_241del p.T79_L81delinsI | In Frame Del (DEL) | VAF 110/256 reads (43%) | called by mutect2, pindel, varscan2
- DGKG | c.2346G>A p.S782= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs368236770; called by muse, varscan2
- GFM1 | c.1722C>T p.F574= | Silent (SNP) | VAF 79/194 reads (41%) | catalogued as rs751810377, COSV51831982; ClinVar: likely benign; called by muse, mutect2, varscan2
- H2BC8 | c.186C>T p.I62= | Silent (SNP) | VAF 52/131 reads (40%) | catalogued as rs921511542; called by muse, mutect2, varscan2
- HTR1A | c.390C>T p.I130= | Silent (SNP) | VAF 254/619 reads (41%) | catalogued as COSV60502710; called by muse, mutect2, varscan2
- KRT2 | c.1230C>T p.I410= | Silent (SNP) | VAF 343/825 reads (42%) | catalogued as rs753421351; called by muse, mutect2, varscan2
- MXRA5 | c.2340G>A p.P780= | Silent (SNP) | VAF 163/187 reads (87%) | catalogued as rs750424330, COSV54237534; called by muse, mutect2, varscan2
- PAGR1 | c.15G>C p.R5= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2
- RYR3 | c.6129G>A p.G2043= | Silent (SNP) | VAF 82/180 reads (46%) | catalogued as rs954764673; called by muse, mutect2, varscan2
- SCN11A | c.414C>T p.T138= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs765162266; called by muse, mutect2, varscan2
- TACR3 | c.60C>T p.D20= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as COSV59208469; called by muse, mutect2, varscan2
- TBC1D17 | c.1938C>T p.A646= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99681026; called by muse, mutect2, varscan2
- TRERF1 | c.3198G>A p.S1066= | Silent (SNP) | VAF 136/370 reads (37%) | catalogued as rs774437302, COSV61668893; called by muse, mutect2, varscan2
- WNT4 | c.873G>A p.T291= | Silent (SNP) | VAF 284/674 reads (42%) | catalogued as rs770489893, COSV51604747; called by muse, mutect2, varscan2
- ZC3H4 | c.3774G>A p.T1258= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as rs566170236; called by muse, mutect2, varscan2
- ZNF214 | c.39A>G p.T13= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.-85+898G>A | Intron (SNP) | VAF 107/312 reads (34%) | catalogued as rs997667968; called by muse, mutect2, varscan2
- FOXP2 | c.*2834G>T | 3'UTR (SNP) | VAF 56/304 reads (18%) | called by mutect2, varscan2
- IQCJ-SCHIP1 | c.291+11150G>T | Intron (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1708-616C>T | Intron (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- MXD3 | chr5:177307159 del CTGTGGTTGGGAGTTCCCCCGTTTTCATTAGGCAAGA | 3'Flank (DEL) | VAF 55/159 reads (35%) | called by mutect2, pindel, varscan2
- NACA | c.71-2527C>T | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as rs1167431335; called by muse, mutect2, varscan2
- NOC2LP2 | n.900G>A | RNA (SNP) | VAF 255/663 reads (38%) | catalogued as rs746287163; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109728C>T | Intron (SNP) | VAF 217/550 reads (39%) | catalogued as COSV58454765, COSV58483796; called by muse, mutect2, varscan2
- RCBTB2 | c.-4C>T | 5'UTR (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- SGIP1 | c.99+992A>G | Intron (SNP) | VAF 47/109 reads (43%) | catalogued as rs767297874, COSV52764888; called by muse, mutect2, varscan2
